Surgical pathology report (de-identified scan), TCGA case TCGA-30-1857, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1857-01A (Primary Tumor).

[page 1 of 2]
Accession Number: [REDACTED] Report Status: Final

Type: Surgical Pathology

Pathology Report [REDACTED] OMENTUM BIOPSY

Accessioned On: [REDACTED]

DIAGNOSIS:

SPECIMEN LABELED "OMENTUM, BIOPSY" (including FSA):

METASTATIC PAPILLARY SEROUS CARCINOMA involving omentum.

SPECIMEN LABELED "OMENTUM, RESECTION":

METASTATIC PAPILLARY SEROUS CARCINOMA involving omentum.

SPECIMEN LABELED "STOMACH MASS, BIOPSY":

METASTATIC PAPILLARY SEROUS CARCINOMA involving a lymph node and adipose tissue.

SPECIMEN LABELED "ADDITIONAL OMENTAL TUMOR", BIOPSY:

METASTATIC PAPILLARY SEROUS CARCINOMA involving omentum.

SPECIMEN LABELED "LEFT ADNEXA:

PAPILLARY SEROUS ADENOCARCINOMA grade 3 (of 3) involving ovary.
and surrounding the fallopian tube.

SPECIMEN LABELED "SMALL BOWEL, SEGMENTAL RESECTION":

METASTATIC PAPILLARY SEROUS CARCINOMA involving the serosal surface of
the small bowel.

The margins of resection are free of tumor.

CLINICAL DATA:

History: [REDACTED] with ascites (positive adenocarcinoma).

Operation: Small bowel resection, radical cytoreductive
exploratory lap.

Clinical Diagnosis: Ascites/pelvic mass.

TISSUE SUBMITTED: 1. Omental biopsy [REDACTED]

2. Omental tumor

3. Tumor from stomach

4. Additional omental tumor

5. Left adnexa

6. Small bowel section

O.R. CONSULTATION:

SPECIMEN LABELED "#1 OMENTAL BIOPSY" [REDACTED]

Metastatic papillary serous carcinoma consistent with
ovarian origin.

GROSS DESCRIPTION:

The specimen is received fresh in six parts, each labeled with the patient's
name and unit number.

Part one, "omenta biopsy", consists of a single fragment of tan/red soft
tissue (6 x 5 x 2 cm) that is diffusely firm and polypoid. Representative
sections are submitted as frozen section A. Representative sections are
submitted.

Micro sections:

Micro 1: frozen section A remnant, 1 frag, [REDACTED]

Micro 2-3: representative sections of omental biopsy, 6 frags [REDACTED]

Part two, "omenta tumor", consists of a segment of omentum (13 x 8 x 2.5 cm)
that is diffusely infiltrated by a tan firm nodular tumor. Representative
sections are submitted.

Micro 4-5: omental tumor, 7 frags, [REDACTED]

Part three, "tumor from stomach", consists of a fragment of tan/pink soft
tissue (5 x 3 x 1.2 cm).

Micro 6-7: tumor from stomach, 3 frags, [REDACTED]

TCGA-30-1857

[page 2 of 2]
Part four, "additional omental tumor", consists of tan/pink firm tissue (7 x 4 x 1.5 cm) from which representative sections are submitted.

Micro 8-9: additional omental tumor, 4 frags,

Part five, "left adnexa", consists of a fragment of tan firm tissue (4 x 3 x 2 cm) with a clear cystic area and possible tan exudate at its surface. Representative sections are submitted.

TCGA-30-1857

Micro 10-11: left adnexa, 4 frags,

Part six, "small bowel section", consists of unoriented segment of bowel (1 cm in length by 3.5 cm in diameter), with stapled resection margins (3 cm and 2.6 cm). On along the surface of the bowel there are multiple implants firm tan tissue measuring up to 1 cm in greatest dimension. Representative sections are submitted. Small implants do not appear to penetrate through the mucosal surface.

Micro 12: unoriented margins, 2 frags,

Micro 13: surface implant, 3 frags,

Micro 14: sections of bowel and tumor, 3 frags

Micro 15: representative section of uninvolved valve, 1 fra

Reports to:

SPECIMEN TYPE: OMENTUM BIOPSY

ADDITIONAL SPECIMEN TYPE: OMENTUM BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: OMENTUM BIOPSY

ADDITIONAL SPECIMEN TYPE: OVARY WITH OR WITHOUT FALLOPIAN TUBE- NEOPLASTIC

ADDITIONAL SPECIMEN TYPE: SMALL INTESTINE RESECTION OTHER THAN FOR TUMOR

Source: NCI Genomic Data Commons file c8180e76-8730-4e3c-b0ca-e6b158c51ec4 (TCGA-30-1857.E3D84909-0149-4691-A398-1A6B272DDE60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).